Surgical pathology report (de-identified scan), TCGA case TCGA-FD-A3N5, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site BLN - University Of Chicago, specimen TCGA-FD-A3N5-01A (Primary Tumor).

[page 1 of 3]
Sample #

Gender: Male

DOB:

Race: Unknown

Report Date:

Pathology Report:

HIHAA Discrepancy		

Surgical Pathology Report

FINAL PATHOLOGIC DIAGNOSIS

A. Right pelvic lymph nodes; dissection:

- Nine lymph nodes, no tumor present (0/9)

B. Left pelvic lymph nodes; dissection:

- Seven lymph nodes, no tumor present (0/7). (See comment).

C. Bladder, prostate, seminal vesicles, vas deferens; cystoprostatectomy:

- Urothelial carcinoma, high grade, with extensive squamous differentiation and keratin production, invasive into muscularis propria.
- No lymphovascular invasion present. - Margins of resection (soft tissue, prostatic urethra, right and left ureter), no tumor present.
- Extensive chronic lymphoplasmacytic inflammatory response and follicular hyperplasia in the extravesical adipose tissue.
- See pathologic parameters and comment.

- Prostate with high grade prostatic intraepithelial neoplasia (PIN).

- Bilateral seminal vesicles and vasa deferentia, no tumor present.

D. Urethral margin; resection:

- Segment of prostatic urethra, no tumor present

Urothelial Carcinoma Pathologic Parameters

1. Tumor type: Urothelial carcinoma with extensive squamous differentiation
2. Grade of tumor: High grade
3. Depth of invasion: Muscularis propria, outer half
4. Tumor distribution: Solitary, 7.0 x 3.5 x 3.0 cm
Involving right wall, anterior wall, posterior wall and dome
5. Ureteral margins: Negative
6. Distal urethral margin: Negative
7. Soft tissue margin: Negative
8. Lymph nodes: Sixteen lymph nodes, no tumor present (0/16)
9. pTNM: pT2b, N0, MX

Effective : this Checklist utilizes the 7th edition TNM staging system for Bladder of the American Joint Committee on Cancer (AJCC) and the

ICD-O-3
Carcinoma, urothelial, NOS 8120/3
Path Site: bladder, NOS C67.9
CQCE bladder, posterior wall C67.4
1/2/12

[page 2 of 3]
Comment

Part B5: The sections show a lymph node with fibrosis and plasmacytic infiltrate. The immunohistochemical stain Cam5.2 is positive in rare dendritic cells.

Part C: The majority of tumor shows extensive squamous differentiation with keratin production (99%).

xxx

[] M.D

Interpretation performed by the Attending Pathologist and reviewed with the Resident/Fellow, [] M.D., Ph.D.

Electronically Signed Out by [] M.D

Clinical History:

The patient is a year-old male with bladder cancer who undergoes prostatectomy and ileal conduit.

Specimens Received:

A: Right pelvic lymphnodes

B: Left pelvic lymphnodes

C: Bladder, prostate, seminal vesicles, vas deferens

D: Urethral margin

Gross Description:

The specimen is received in four containers, each labeled with the patient's name and medical record number.

A. The first container is additionally designated "1. right pelvic lymph nodes". Received fresh and placed in formalin is a 5.0 x 4.0 x 3.0 cm aggregate of fibrofatty tissue which is dissected to reveal multiple tentative lymph nodes range in size from 0.5 to 2.5 cm. The lymph nodes are entirely submitted as follows:

A1-A5: one node, bisected in each cassette

A6: four lymph nodes

B. The second container is additionally designated "2. left pelvic lymph nodes". Received fresh and placed in formalin is a 6.5 x 4.5 x 2.0 cm aggregate of fibrofatty tissue which is dissected to reveal multiple tentative lymph nodes range in size from 0.5 to 3.0 cm. The lymph nodes are entirely submitted as follows:

B1-B2: largest node, bisected

B3: one lymph node, bisected

B4: one lymph node, bisected

B5: four lymph nodes between sponges

B6: adjacent fibrous tissue.

C. The third container is additionally designated "3. bladder, prostate, seminal vesicles, vas deferens". Received fresh and placed in formalin is a 303 gram, 14.5 x 9.5 x 3.0 cm cystoprostatectomy specimen with attached mesenteric fat. The bladder measures 9.0 x 8.0 x 3.0 cm. The right ureteral stump measures 0.5 cm and the left 0.3 cm. Both demonstrate patent lumina. The prostate measures 4.5 x 4.3 x 4.0 cm. The right seminal vesicle measures 4.5 x

[page 3 of 3]
3.5 x 2.0 cm. The right vas deferens measures 8.5 x 1.0 cm. The left seminal vesicles measures 4.0 x 3.0 x 1.5 cm. The left vas deferens measures 4.5 x 1.0 cm. The right half of the prostate and bladder is inked blue and the left half is inked black. The prostate is opened anteriorly along the urethra and continues superiorly through the bladder in a Y-shaped incision. The prostate is serially sectioned from apex to base to reveal a firm white 0.6 cm nodule grossly abutting the black inked margin. The remainder of the prostate is unremarkable. The seminal vesicles are markedly dilated and filled with a yellow-green gelatinous fluid. The bladder demonstrates a 7.0 x 3.5 x 3.0 cm fungating friable yellow-tan mass grossly involving the right wall, anterior wall, posterior wall and the dome of the bladder. Serially sectioning reveals tumor invasion into the muscularis propria to a depth of 3.0 cm extending to within 0.5 cm of the inked margin. The remainder of the bladder mucosa is tan-brown, edematous and glistening with a uniform 0.3 cm wall thickness. The bilateral ureteral orifices are identified and probe patent. Representative sections are submitted as follows:

- C1: urethral margin
- C2: right ureteral margin, between sponges
- C3: left ureteral margin, between sponges
- C4: prostatic apical margin
- C5-C11: representative prostate
- C12: seminal vesicles and vasa deferentia
- C13-C18: mass from inferior to superior
- C19: right ureteral orifice
- C20: left ureteral orifice
- C21: dome
- C22: anterior wall
- C23: posterior wall
- C24: left wall
- C25: trigone

D. The fourth container is additionally designated "4. urethral margin". Received fresh and placed in formalin is an unremarkable-oriented 1.5 x 1.0 x 0.5 cm portion of tissue which is focally cauterized. The specimen is serially sectioned and entirely submitted in cassette D1.

xxx

[], M.D.

Source: NCI Genomic Data Commons file 9e29bd07-a597-4379-8855-9aedb905fcb4 (TCGA-FD-A3N5.9E5D7033-E1B3-47A8-9526-D45B3113A54C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).